Somatic mutation profile of cancer-model specimen HCM-BROD-0002-C71-85A (2D Modified Conditionally Reprogrammed Cells, passage 9; aliquot HCM-BROD-0002-C71-85A-01D-A768-36), derived from the primary tumor of HCMI case HCM-BROD-0002-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Gliosarcoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 66.3 years (24,213 days).
Specimen HCM-BROD-0002-C71-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 2D Modified Conditionally Reprogrammed Cells; Preservation method: Frozen; Passage count: 9.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df8942cb-7b99-49ca-a4dc-f6cfe94d7936.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0002-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0002-C71-10A-01D-A77E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/00f76ccf-6daf-414f-83c5-501a44739a72

The open-access MAF lists 114 somatic variants for this specimen: 78 protein-altering or splice-affecting, 25 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, Silent 25, Intron 6, Frame Shift Del 4, Nonsense Mutation 4, 3'UTR 3, 5'UTR 1, Splice Site 1, Frame Shift Ins 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 103/105 reads (98%) | hotspot (GDC flag); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.814G>A p.V272M | Missense Mutation (SNP) | VAF 310/311 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912657, CM130241, CM920676, COSV52661812, COSV52677483, COSV52701127; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADGRB2 | c.991G>A p.V331M | Missense Mutation (SNP) | VAF 137/298 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV99927139; called by muse, mutect2, varscan2
- ARHGAP44 | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 8/179 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52390291; called by muse, mutect2
- BRF2 | c.1181G>A p.R394H | Missense Mutation (SNP) | VAF 85/170 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs144896527; called by muse, mutect2, varscan2
- CCN4 | c.511C>T p.R171W | Missense Mutation (SNP) | VAF 21/345 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs140971140; called by muse, mutect2
- CEACAM3 | c.463G>A p.G155S | Missense Mutation (SNP) | VAF 75/75 reads (100%) | SIFT tolerated (0.16); PolyPhen benign (0.038); catalogued as rs528553937; called by muse, mutect2, varscan2
- CNR2 | c.815C>T p.T272M | Missense Mutation (SNP) | VAF 105/234 reads (45%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.806); catalogued as rs201049279; called by muse, mutect2, varscan2
- EDAR | c.607G>A p.V203I | Missense Mutation (SNP) | VAF 110/210 reads (52%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); catalogued as rs148212997; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ELFN1 | c.1969G>A p.V657I | Missense Mutation (SNP) | VAF 100/281 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0.014); catalogued as rs1206191418; called by muse, mutect2, varscan2
- FAM186A | c.5491C>T p.P1831S | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.077); catalogued as rs1295245661, COSV100525170; called by muse, mutect2, varscan2
- FBXO25 | c.384G>A p.L128= (on ENST00000382824 / NM_183421.2; = p.L61= on NM_012173.3) | Splice Region (SNP) | VAF 44/87 reads (51%) | catalogued as rs377735335; called by muse, mutect2, varscan2
- GALNT14 | c.1120C>T p.R374W | Missense Mutation (SNP) | VAF 118/244 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1422310831, COSV100203898, COSV61110516; called by muse, mutect2, varscan2
- IL17F | c.361G>A p.V121I | Missense Mutation (SNP) | VAF 225/453 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.537); catalogued as rs550486674, COSV60233991; called by muse, mutect2, varscan2
- IL21R | c.1058C>T p.P353L | Missense Mutation (SNP) | VAF 146/302 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs550842554, COSV100559944; called by muse, mutect2, varscan2
- KSR2 | c.2807G>A p.R936H | Missense Mutation (SNP) | VAF 195/319 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs550563327, CM1311380; called by muse, mutect2, varscan2
- LIPH | c.922G>A p.G308R | Missense Mutation (SNP) | VAF 56/141 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as COSV99956296; called by muse, mutect2, varscan2
- LRRN1 | c.1280C>T p.S427F | Missense Mutation (SNP) | VAF 7/135 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV60016219; called by muse, mutect2
- MEIG1 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 16/161 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); catalogued as rs776040423, COSV65542397; called by muse, mutect2, varscan2
- MYO1D | c.1598G>A p.R533H | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772624904, COSV100554719; called by muse, mutect2, varscan2
- OBSCN | c.9697C>T p.R3233C | Missense Mutation (SNP) | VAF 223/488 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs367605500; called by muse, mutect2, varscan2
- OR6A2 | c.715C>T p.R239C | Missense Mutation (SNP) | VAF 86/208 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.051); catalogued as rs778988808, COSV100215782, COSV60264834; called by muse, mutect2, varscan2
- PCDH11Y | c.2569G>A p.V857I (on ENST00000400457 / NM_032973.2; = p.V846I on NM_032971.3) | Missense Mutation (SNP) | VAF 93/112 reads (83%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs777010130, COSV53075849; called by muse, mutect2, varscan2
- PRKACG | c.305C>T p.P102L | Missense Mutation (SNP) | VAF 184/315 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370025582; called by muse, mutect2, varscan2
- PTPRQ | c.6830A>T p.Q2277L (on ENST00000616559; = p.Q2244L on NM_001145026.2) | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57049635; called by muse, mutect2, varscan2
- RP1 | c.1298G>A p.S433N | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as rs971203515; called by muse, mutect2, varscan2
- STK31 | c.316G>A p.V106I | Missense Mutation (SNP) | VAF 68/298 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs150391003; called by muse, mutect2, varscan2
- TBC1D8 | c.757C>T p.R253* | Nonsense Mutation (SNP) | VAF 140/290 reads (48%) | catalogued as rs747957096, COSV65210358; called by muse, mutect2, varscan2
- TCHH | c.5576G>A p.R1859H | Missense Mutation (SNP) | VAF 20/225 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as rs367821937; called by muse, mutect2
- TDRD7 | c.623C>A p.T208N | Missense Mutation (SNP) | VAF 9/202 reads (4%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as rs1298509646; called by muse, mutect2
- TENT5C | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 135/312 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs750792861, COSV65616442; called by muse, mutect2, varscan2
- TMEM43 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 181/392 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758817244; called by muse, mutect2, varscan2
- TOLLIP | c.331G>T p.G111C | Missense Mutation (SNP) | VAF 90/202 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55136740; called by muse, mutect2, varscan2
- TRIP6 | c.892C>A p.R298S | Missense Mutation (SNP) | VAF 80/334 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV52341842; called by muse, mutect2, varscan2
- TTC29 | c.1406G>T p.G469V | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.005); catalogued as rs1454013515; called by muse, mutect2, varscan2
- TTN | c.37478G>A p.R12493Q (on ENST00000591111; = p.R5069Q on NM_003319.4) | Missense Mutation (SNP) | VAF 76/157 reads (48%) | PolyPhen benign (0.001); catalogued as rs764083952, COSV59943321; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZBED6 | c.1278C>G p.N426K | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as rs190516745; called by muse, mutect2, varscan2
- ZFAND5 | c.554A>G p.N185S | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.114); catalogued as COSV99428445; called by muse, mutect2, varscan2
- ACTR2 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 74/142 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- ADAM22 | c.2320del p.Y774Mfs*2 | Frame Shift Del (DEL) | VAF 25/135 reads (19%) | called by mutect2, pindel
- ANKRD30A | c.1779A>T p.K593N (on ENST00000611781; = p.K537N on NM_052997.2) | Missense Mutation (SNP) | VAF 80/123 reads (65%) | SIFT tolerated (0.52); PolyPhen benign (0.05); called by muse, varscan2
- CLUAP1 | c.730G>T p.E244* | Nonsense Mutation (SNP) | VAF 42/74 reads (57%) | called by muse, mutect2
- CTSV | c.84G>C p.K28N | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CUL2 | c.779C>T p.T260I | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CYP4X1 | c.705C>G p.D235E | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- DCDC1 | c.797G>A p.G266E | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DEK | c.634G>A p.G212R | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- DST | c.8906T>C p.L2969P | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- EGFR | c.1548G>C p.W516C | Missense Mutation (SNP) | VAF 16/413 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EPHX4 | c.1084del p.D362Ifs*12 | Frame Shift Del (DEL) | VAF 17/36 reads (47%) | called by mutect2, varscan2
- ERLEC1 | c.968C>T p.T323I | Missense Mutation (SNP) | VAF 125/233 reads (54%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.605); called by muse, mutect2, varscan2
- EVC2 | c.1867del p.L623Sfs*38 | Frame Shift Del (DEL) | VAF 118/348 reads (34%) | called by mutect2, pindel, varscan2
- FAM221B | c.1199G>A p.R400K | Missense Mutation (SNP) | VAF 6/148 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.391); called by muse, mutect2
- GALNT13 | c.884T>A p.F295Y | Missense Mutation (SNP) | VAF 79/154 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- HSP90AA1 | c.973G>A p.A325T | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.846); called by muse, mutect2
- ITGA2 | c.625A>G p.T209A | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.039); called by muse, mutect2
- MAEL | c.713A>T p.Q238L | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.073); called by muse, mutect2
- MSL3 | c.645del p.K215Nfs*26 (on ENST00000312196 / NM_078629.4; = p.K49Nfs*26 on NM_006800.4) | Frame Shift Del (DEL) | VAF 57/61 reads (93%) | called by mutect2, pindel*, varscan2
- MYLK | c.1850C>T p.P617L | Missense Mutation (SNP) | VAF 12/374 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2
- NOP58 | c.292A>G p.I98V | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- OR52M1 | c.79G>T p.V27F | Missense Mutation (SNP) | VAF 56/110 reads (51%) | SIFT tolerated (0.26); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PFKFB3 | c.948G>T p.E316D | Missense Mutation (SNP) | VAF 13/109 reads (12%) | PolyPhen benign (0.276); called by muse, mutect2, varscan2
- PIGR | c.2140+1G>T p.X714_splice | Splice Site (SNP) | VAF 12/170 reads (7%) | called by muse, mutect2
- POT1 | c.891G>C p.L297F | Missense Mutation (SNP) | VAF 10/296 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.024); called by muse, mutect2
- PRAMEF7 | c.113C>T p.T38M | Missense Mutation (SNP) | VAF 306/311 reads (98%) | SIFT deleterious (0.01); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- PRR22 | c.803A>T p.K268M | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.299); called by muse, mutect2
- PTPN23 | c.3578_3579insA p.V1194Cfs*12 | Frame Shift Ins (INS) | VAF 99/242 reads (41%) | called by mutect2, pindel, varscan2
- RAET1L | c.487C>A p.P163T | Missense Mutation (SNP) | VAF 16/342 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2
- RFTN1 | c.868C>G p.Q290E | Missense Mutation (SNP) | VAF 116/238 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- RPTN | c.628G>T p.V210L | Missense Mutation (SNP) | VAF 28/370 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SATL1 | c.787G>T p.V263F (on ENST00000395409; = p.V450F on NM_001012980.2) | Missense Mutation (SNP) | VAF 198/199 reads (99%) | SIFT tolerated (0.7); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- SLC45A2 | c.728C>G p.T243R | Missense Mutation (SNP) | VAF 170/352 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- STAT6 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 18/229 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TRPV6 | c.1591A>C p.M531L | Missense Mutation (SNP) | VAF 119/592 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZFP92 | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 130/130 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- ZNF214 | c.583G>T p.E195* | Nonsense Mutation (SNP) | VAF 12/137 reads (9%) | called by muse, mutect2
- ZNF735 | c.1100C>A p.T367N | Missense Mutation (SNP) | VAF 134/538 reads (25%) | SIFT tolerated (0.78); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF816 | c.1308T>A p.S436R | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT tolerated (0.61); PolyPhen benign (0.006); called by muse, mutect2
- ACSM5 | c.1101C>T p.Y367= | Silent (SNP) | VAF 208/424 reads (49%) | catalogued as rs369835056; called by muse, mutect2, varscan2
- ACTRT1 | c.621C>T p.L207= | Silent (SNP) | VAF 18/139 reads (13%) | called by muse, mutect2, varscan2
- ADCY4 | c.531C>T p.N177= | Silent (SNP) | VAF 55/109 reads (50%) | catalogued as rs376126420; called by muse, mutect2, varscan2
- ASMT | c.135C>T p.D45= | Silent (SNP) | VAF 76/435 reads (17%) | catalogued as rs202194252; called by muse, mutect2, varscan2
- CC2D2A | c.1656T>A p.I552= | Silent (SNP) | VAF 9/69 reads (13%) | called by muse, mutect2, varscan2
- COL1A1 | c.4056G>A p.L1352= | Silent (SNP) | VAF 148/305 reads (49%) | called by muse, mutect2, varscan2
- DLK1 | c.1014C>A p.R338= | Silent (SNP) | VAF 56/147 reads (38%) | called by muse, mutect2, varscan2
- ECE2 | c.177G>A p.T59= | Silent (SNP) | VAF 94/172 reads (55%) | called by muse, mutect2, varscan2
- ERCC6 | c.2901C>T p.T967= | Silent (SNP) | VAF 73/291 reads (25%) | called by muse, varscan2
- FAM124B | c.1140C>T p.G380= | Silent (SNP) | VAF 133/269 reads (49%) | catalogued as rs375635395; called by muse, mutect2, varscan2
- FBXL4 | c.315T>C p.D105= | Silent (SNP) | VAF 6/122 reads (5%) | called by muse, mutect2
- IFT172 | c.4731C>T p.F1577= | Silent (SNP) | VAF 28/188 reads (15%) | called by mutect2, varscan2
- KRT14 | c.144C>T p.G48= | Silent (SNP) | VAF 99/206 reads (48%) | catalogued as rs1254536871, COSV51421894; called by muse, mutect2, varscan2
- NLRC3 | c.921C>A p.A307= | Silent (SNP) | VAF 25/224 reads (11%) | catalogued as COSV57087294; called by muse, mutect2, varscan2
- NLRP7 | c.792G>A p.A264= | Silent (SNP) | VAF 149/151 reads (99%) | catalogued as rs141553552; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1428C>T p.D476= (on ENST00000259318 / NM_001136562.3; = p.D707= on NM_007203.5) | Silent (SNP) | VAF 48/102 reads (47%) | catalogued as rs552999944; called by muse, mutect2, varscan2
- PBX4 | c.501G>A p.R167= | Silent (SNP) | VAF 51/157 reads (32%) | called by muse, mutect2, varscan2
- PCDH9 | c.3273C>T p.D1091= (on ENST00000377865 / NM_203487.3; = p.D1057= on NM_020403.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/168 reads (10%) | catalogued as rs372281341; called by muse, mutect2, varscan2
- SNED1 | c.3603C>T p.G1201= | Silent (SNP) | VAF 141/310 reads (45%) | catalogued as rs369849516; called by muse, varscan2
- SYDE1 | c.1911C>T p.P637= | Silent (SNP) | VAF 126/226 reads (56%) | called by muse, mutect2, varscan2
- TJP2 | c.1044C>T p.D348= | Silent (SNP) | VAF 102/216 reads (47%) | catalogued as rs750420311; called by muse, mutect2, varscan2
- TUBB4A | c.690G>A p.S230= | Silent (SNP) | VAF 20/698 reads (3%) | catalogued as rs1368586638, COSV51168489; called by muse, mutect2
- USH2A | c.13434A>G p.E4478= | Silent (SNP) | VAF 137/292 reads (47%) | called by muse, mutect2, varscan2
- WDR13 | c.483G>A p.A161= | Silent (SNP) | VAF 146/146 reads (100%) | catalogued as rs1009484702; called by muse, mutect2, varscan2
- XIRP2 | c.5994A>G p.G1998= (on ENST00000628543; = p.G2173= on NM_152381.6) | Silent (SNP) | VAF 11/118 reads (9%) | called by muse, mutect2
- EML3 | c.2487+28G>T | Intron (SNP) | VAF 10/157 reads (6%) | called by muse, mutect2
- FAM227B | c.1013-24889G>A | Intron (SNP) | VAF 10/10 reads (100%) | catalogued as rs555267524; called by muse, mutect2, varscan2
- FAS | c.*1303C>A | 3'UTR (SNP) | VAF 31/31 reads (100%) | called by muse, mutect2, varscan2
- KRT14 | c.1322-25C>G | Intron (SNP) | VAF 86/184 reads (47%) | called by muse, mutect2
- LARGE1 | c.616-7132A>T | Intron (SNP) | VAF 7/83 reads (8%) | called by muse, mutect2
- LYNX1-SLURP2 | c.*202C>A | 3'UTR (SNP) | VAF 109/219 reads (50%) | called by muse, mutect2, varscan2
- NKD2 | c.*44C>T | 3'UTR (SNP) | VAF 190/418 reads (45%) | catalogued as rs762186974; called by muse, varscan2
- NPIPP1 | n.914C>G | RNA (SNP) | VAF 335/763 reads (44%) | catalogued as rs759043989, COSV100722054; called by muse, mutect2, varscan2
- PHGDH | c.356+1413A>G | Intron (SNP) | VAF 18/496 reads (4%) | called by muse, mutect2
- SMARCAL1 | c.1711-326G>A | Intron (SNP) | VAF 16/48 reads (33%) | catalogued as rs1326414347, COSV61924553; called by muse, mutect2, varscan2
- SUCO | c.-231C>G | 5'UTR (SNP) | VAF 11/128 reads (9%) | called by muse, mutect2
